CGCI case HTMCP-02-01-01249 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/f92ec8ab-69ac-4890-a349-156b0aff2c7f

Demographics
Sex at birth: male.

Molecular and laboratory tests
- Test (IHC): Positive; Specialized molecular test: P40.

Biospecimens (3 samples)
- Sample HTMCP-02-01-01249-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-01-01249-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-02-01-01249-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-01-01249-01A-01E-17519:
- % tumour top: 50
- % tumour bottom: 50

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-01-01249-01A-01S-17519:
- % tumour top: 50
- % tumour bottom: 50
